Gene-level copy-number profile of tumor specimen TCGA-SH-A9CT-01A from TCGA case TCGA-SH-A9CT, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 67.2 years (24,528 days).
Specimen TCGA-SH-A9CT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.dc18ad78-2fc6-4362-8030-243cd5c57914.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SH-A9CT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c68c0901-1ffa-4ad5-aa7b-73553791b524

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 16,441; copy number 2: 39,120; copy number 3: 2,730; copy number 4: 1,462; copy number 5: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SH-A9CT-01A-11D-A39Q-01): tumor purity 0.73, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:30,425,265–30,537,381, 13 genes: KRTAP13-3, KRTAP13-4, KRTAP13-5P, KRTAP15-1, KRTAP19-1, KRTAP19-2, KRTAP19-3, KRTAP19-4, KRTAP19-5, KRTAP19-9P, KRTAP19-10P, AP000567.1, KRTAP19-11P.
- chr21:30,718,525–30,755,428, 4 genes: KRTAP21-3, KRTAP21-4P, KRTAP21-2, KRTAP21-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 39 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:221,330,080–223,665,723, 39 genes, copy number 5 (within-gene range 4–5): LINC02817, AL360013.2, AL360013.3, AL360013.1, AL360013.4, DUSP10, LINC01655, RNU6-403P, LINC02257, LINC02474, LINC01705, AL356108.1, QRSL1P2, AL513314.1, CICP13, AL513314.2, RNU6-791P, AL592148.2, HHIPL2, TAF1A, TAF1A-AS1, MIA3, AL592148.1, AL592148.3, AIDA, BROX, FAM177B, AL392172.1, DISP1, NDUFB1P2, AL929091.1, TLR5, AL359979.2, AL359979.1, SUSD4, RNU4-57P, CCDC185, CAPN8, SNRPEP10.

Autosomal genes at a single copy (total copy number 1): 14,055. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
